Somatic mutation profile of tumor specimen TCGA-UB-A7MA-01A (aliquot TCGA-UB-A7MA-01A-11D-A33Q-10) from TCGA case TCGA-UB-A7MA, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Combined hepatocellular carcinoma and cholangiocarcinoma; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 62.5 years (22,843 days).
Specimen TCGA-UB-A7MA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4a25edd-46a0-4f76-88aa-77f1db451ed4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UB-A7MA-10A (Blood Derived Normal), aliquot TCGA-UB-A7MA-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3aadee7d-045a-4697-b014-cc9c751f2f20

The open-access MAF lists 97 somatic variants for this specimen: 67 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 27, Frame Shift Del 4, Frame Shift Ins 2, Splice Site 2, Intron 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.2154+1G>A p.X718_splice (on ENST00000404938 / NM_001163941.2; = p.X273_splice on NM_178559.6) | Splice Site (SNP) | VAF 15/62 reads (24%) | catalogued as rs756265243, COSV51714310; called by muse, mutect2, varscan2
- AC004593.2 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs373908314; called by muse, mutect2, varscan2
- ADAM12 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs927992573, COSV64106760, COSV64109341; called by muse, mutect2, varscan2
- ANKRD30A | c.1336A>G p.R446G (on ENST00000611781; = p.R390G on NM_052997.2) | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as COSV64615032; called by muse, mutect2, varscan2
- ASXL3 | c.1698G>C p.E566D | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as COSV52471954; called by muse, mutect2, varscan2
- ATG2A | c.5815_5816del p.*1939Sfs*16 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs771615064; called by pindel, varscan2
- ATR | c.4541G>T p.C1514F | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63388126, COSV63388516; called by muse, mutect2, varscan2
- BDNF | c.523G>C p.G175R | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59236501; called by muse, mutect2, varscan2
- CASR | c.1127G>A p.G376D | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV56139152; called by muse, mutect2, varscan2
- CASS4 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV64387357; called by muse, mutect2, varscan2
- CFLAR | c.59T>C p.M20T | Missense Mutation (SNP) | VAF 69/116 reads (59%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV57937853; called by muse, mutect2, varscan2
- CHL1 | c.3388G>A p.D1130N (on ENST00000397491 / NM_001253387.1; = p.D1146N on NM_006614.4) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV56597894; called by muse, mutect2, varscan2
- CIART | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.06); catalogued as COSV51745007; called by muse, mutect2, varscan2
- COPA | c.2606C>T p.A869V | Missense Mutation (SNP) | VAF 126/221 reads (57%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV54105408; called by muse, mutect2, varscan2
- CRYZL1 | c.156A>C p.E52D | Missense Mutation (SNP) | VAF 112/295 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV51678473; called by muse, mutect2, varscan2
- CTU2 | c.1275G>C p.E425D | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as COSV56339953; called by muse, varscan2
- DCDC1 | c.4889C>A p.T1630K (on ENST00000597505 / NM_001367979.1; = p.T737K on NM_020869.3) | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.372); catalogued as COSV58000791; called by muse, mutect2, varscan2
- DRG2 | c.461T>C p.V154A | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.478); catalogued as COSV56728754; called by muse, mutect2, varscan2
- DYTN | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV71752503; called by muse, mutect2, varscan2
- ELAC2 | c.1226G>A p.G409D | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.56); PolyPhen benign (0.021); catalogued as rs1567754588, COSV100568529, COSV62033327; called by muse, mutect2, varscan2
- FAM47A | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV60498260, COSV99080508; called by muse, mutect2, varscan2
- FRYL | c.8359G>A p.D2787N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV51938900; called by muse, mutect2, varscan2
- FXYD4 | c.146C>A p.A49D | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV72052710; called by muse, mutect2, varscan2
- GLUD1 | c.1315T>C p.Y439H | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53279928; called by muse, mutect2
- GPR50 | c.337G>T p.V113F | Missense Mutation (SNP) | VAF 86/176 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV54438966, COSV54440765; called by muse, mutect2, varscan2
- GRAMD1B | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV59207501; called by muse, mutect2, varscan2
- GRIA3 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 99/221 reads (45%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.987); catalogued as COSV52070362; called by muse, mutect2, varscan2
- H1-2 | c.255G>C p.K85N | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59191504, COSV59191681; called by muse, mutect2, varscan2
- JUND | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs751981092, COSV53254770; called by muse, mutect2
- KCNE4 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as rs750286653, COSV56054846; called by muse, mutect2, varscan2
- KIAA1217 | c.2269C>T p.L757F | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs560134199, COSV56819398; called by muse, mutect2, varscan2
- LRCH2 | c.134C>A p.T45N | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100406693; called by mutect2, varscan2
- LRIT1 | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs773186591, COSV64513104; called by muse, mutect2, varscan2
- MAP3K5 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs1439371428, COSV62890303; called by muse, mutect2, varscan2
- MOCS1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57936512; called by muse, mutect2, varscan2
- MUC16 | c.40702T>C p.Y13568H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as COSV66694486; called by muse, mutect2, varscan2
- NCKAP5 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV58458399, COSV58476499; called by muse, mutect2, varscan2
- NCKAP5 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV58458429; called by muse, mutect2, varscan2
- NCOA3 | c.2795C>G p.P932R | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV59070682; called by muse, mutect2, varscan2
- NEU2 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs748593843, COSV52093319; called by muse, mutect2, varscan2
- NINL | c.4013C>G p.A1338G | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV54005276; called by muse, mutect2, varscan2
- PCDHA3 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782306537, COSV63543579; called by muse, mutect2, varscan2
- PGAP4 | c.577T>G p.Y193D | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV66388036; called by muse, mutect2, varscan2
- PLG | c.2402C>T p.T801I | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.335); catalogued as COSV100369042; called by muse, mutect2, varscan2
- POU6F2 | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs535259814, COSV68877006; called by muse, mutect2, varscan2
- PPM1E | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57576757; called by muse, mutect2, varscan2
- PSMF1 | c.779A>C p.H260P | Missense Mutation (SNP) | VAF 62/103 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55674836; called by muse, mutect2, varscan2
- PVR | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV51823806; called by muse, mutect2, varscan2
- RAB4B | c.184del p.W62Gfs*12 | Frame Shift Del (DEL) | VAF 229/364 reads (63%) | catalogued as rs766157650; called by mutect2, pindel, varscan2
- RNF213 | c.7090G>A p.D2364N | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.167); catalogued as rs757174029, COSV60389849; called by muse, mutect2, varscan2
- SORCS1 | c.2321C>T p.S774F | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV53884447; called by muse, mutect2, varscan2
- SORCS3 | c.2614T>G p.F872V | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV63796502; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.723del p.Y242Tfs*54 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as COSV60346119; called by mutect2, pindel, varscan2
- STK25 | c.574T>C p.Y192H | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99884381; called by muse, mutect2
- SUGP2 | c.545A>G p.E182G | Missense Mutation (SNP) | VAF 90/532 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV58261660; called by muse, mutect2, varscan2
- TBX1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs759363148, COSV60354298; called by muse, mutect2, varscan2
- TCF20 | c.1283C>G p.P428R | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV59493810; called by muse, mutect2, varscan2
- TEX15 | c.1350G>T p.R450S (on ENST00000256246; = p.R833S on NM_001350162.2) | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV56349546; called by muse, mutect2, varscan2
- TFAP2D | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV50431886; called by muse, mutect2, varscan2
- UNC79 | c.7067C>A p.T2356N (on ENST00000393151 / NM_001346218.2; = p.T2179N on NM_020818.5) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56379160; called by muse, mutect2, varscan2
- XIRP2 | c.7231G>C p.E2411Q (on ENST00000628543; = p.E2586Q on NM_152381.6) | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV54687370, COSV54715184; called by muse, mutect2, varscan2
- ZKSCAN3 | c.896G>A p.G299D | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as COSV52853235; called by muse, mutect2, varscan2
- ZNF334 | c.1655C>G p.T552S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV61619340; called by muse, mutect2, varscan2
- MARK2 | c.230_234+9del p.X77_splice | Splice Site (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- PCNX1 | c.4304dup p.L1435Ffs*19 | Frame Shift Ins (INS) | VAF 10/68 reads (15%) | called by mutect2, pindel, varscan2
- RYR2 | c.543_544dup p.I182Tfs*3 | Frame Shift Ins (INS) | VAF 18/83 reads (22%) | called by mutect2, pindel, varscan2
- ZFPL1 | c.553del p.R185Gfs*14 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- ACAN | c.5757G>A p.S1919= | Silent (SNP) | VAF 60/117 reads (51%) | catalogued as rs778250246, COSV61364322; called by muse, mutect2, varscan2
- ADAMTS2 | c.2052C>T p.D684= | Silent (SNP) | VAF 42/87 reads (48%) | catalogued as rs370799965, COSV52364463; called by muse, mutect2, varscan2
- ADGRV1 | c.7770C>T p.S2590= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as rs201767905, CD122146, COSV67978296; called by muse, mutect2, varscan2
- AKT2 | c.582C>A p.V194= | Silent (SNP) | VAF 118/152 reads (78%) | catalogued as COSV60908096, COSV60909221; called by muse, mutect2, varscan2
- COL15A1 | c.558C>A p.P186= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV66647105; called by muse, mutect2, varscan2
- COL16A1 | c.3330C>T p.T1110= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs200246591, COSV54709942; called by muse, mutect2, varscan2
- COQ8A | c.1095C>A p.A365= | Silent (SNP) | VAF 54/90 reads (60%) | catalogued as COSV64658358; called by muse, mutect2, varscan2
- CR2 | c.2814T>A p.T938= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as COSV65508599; called by muse, mutect2, varscan2
- CUL3 | c.1467A>G p.Q489= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs371616108; called by muse, mutect2, varscan2
- CUL7 | c.5016C>T p.T1672= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV54819403; called by muse, mutect2, varscan2
- DMGDH | c.2224C>T p.L742= | Silent (SNP) | VAF 83/223 reads (37%) | catalogued as rs757937639, COSV54865975; called by muse, mutect2, varscan2
- DMRTA2 | c.342G>C p.A114= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV68672778; called by muse, varscan2
- DOCK6 | c.255G>T p.L85= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV53917889; called by muse, mutect2, varscan2
- DOCK7 | c.3558G>A p.L1186= (on ENST00000635253 / NM_001367561.1; = p.L1155= on NM_033407.3) | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as rs761731303, COSV52012822; called by muse, mutect2, varscan2
- DZANK1 | c.1317C>T p.F439= (on ENST00000262547 / NM_001099407.1; = p.F246= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/153 reads (26%) | catalogued as rs747295212, COSV52753719; called by muse, mutect2, varscan2
- GGT5 | c.474C>G p.P158= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV54071213; called by muse, mutect2, varscan2
- HAO1 | c.240G>T p.T80= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV66492825; called by muse, mutect2, varscan2
- HIVEP3 | c.5181G>A p.P1727= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as rs753210157, COSV56018691; called by muse, mutect2, varscan2
- MBTPS1 | c.1236G>A p.G412= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as COSV58571660; called by muse, mutect2, varscan2
- MIA | c.33C>T p.I11= | Silent (SNP) | VAF 71/117 reads (61%) | catalogued as COSV54571817; called by muse, mutect2, varscan2
- MRPL21 | c.580C>A p.R194= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV62913734; called by muse, mutect2, varscan2
- PDE10A | c.1122G>A p.T374= | Silent (SNP) | VAF 52/83 reads (63%) | catalogued as rs765231391, COSV63050108; called by muse, mutect2, varscan2
- PDE8B | c.753G>C p.L251= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as COSV53740753; called by muse, mutect2, varscan2
- SEMA5B | c.2064G>A p.Q688= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV52102579; called by muse, mutect2, varscan2
- SPTA1 | c.1947G>A p.E649= | Silent (SNP) | VAF 68/101 reads (67%) | catalogued as COSV63755551; called by muse, mutect2, varscan2
- TLL1 | c.1695A>G p.A565= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as rs758162833, COSV50303452; called by muse, mutect2, varscan2
- XKR7 | c.1188C>T p.A396= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV73813293; called by muse, mutect2, varscan2
- FGFR1 | c.937-1199G>A | Intron (SNP) | VAF 26/108 reads (24%) | catalogued as COSV100247805; called by muse, mutect2, varscan2
- MAP4K1 | c.*4T>G | 3'UTR (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- MYCBPAP | c.-7C>T | 5'UTR (SNP) | VAF 36/214 reads (17%) | catalogued as COSV60409624; called by muse, varscan2
